Somatic mutation profile of tumor specimen TCGA-AD-6888-01A (aliquot TCGA-AD-6888-01A-11D-1924-10) from TCGA case TCGA-AD-6888, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.4 years (26,816 days).
Specimen TCGA-AD-6888-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b2f78e8-3269-45f6-8638-af499a3752b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-6888-10A (Blood Derived Normal), aliquot TCGA-AD-6888-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ef10483-aaf5-42b8-8325-580b9f2413c6

The open-access MAF lists 111 somatic variants for this specimen: 87 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 19, Nonsense Mutation 11, Intron 2, Frame Shift Del 2, RNA 2, In Frame Del 2, Splice Site 1, 5'UTR 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 50/102 reads (49%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4012C>T p.Q1338* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | hotspot (GDC flag); catalogued as rs121913327, CM930029, COSV57325971; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 273/303 reads (90%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 43/107 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 33/52 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.926G>C p.S309T | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV50745260; called by muse, mutect2, varscan2
- AMFR | c.326C>G p.P109R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV51923218; called by muse, mutect2, varscan2
- ASIC5 | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV101539802; called by muse, mutect2
- ATP1A4 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.317); catalogued as rs755588909, COSV63627737; called by muse, mutect2, varscan2
- ATP8A1 | c.250del p.I84Lfs*26 | Frame Shift Del (DEL) | VAF 39/210 reads (19%) | catalogued as COSV52542857; called by mutect2, pindel, varscan2
- ATXN2 | c.2750A>G p.N917S (on ENST00000550104; = p.N757S on NM_002973.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101112907; called by muse, mutect2, varscan2
- BATF | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54375717; called by muse, mutect2, varscan2
- C1orf159 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs749632934, COSV99618868; called by muse, mutect2, varscan2
- CCT6B | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs749788960, COSV58489848; called by muse, mutect2, varscan2
- CD5 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138915999, COSV61719063; called by muse, mutect2, varscan2
- CDAN1 | c.3519G>C p.E1173D | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs1213905935, COSV51910405; called by muse, mutect2, varscan2
- CNTNAP1 | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as rs781513422, COSV52852759; called by muse, mutect2, varscan2
- COLEC12 | c.1036A>C p.I346L | Missense Mutation (SNP) | VAF 87/146 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.13); catalogued as COSV68372499; called by muse, mutect2, varscan2
- DCLK1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55192408; called by muse, mutect2, varscan2
- DIAPH1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53881525; called by muse, mutect2, varscan2
- DIP2C | c.1388G>T p.W463L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55170844; called by muse, mutect2, varscan2
- DOCK3 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.921); catalogued as rs377200419, COSV56552898; called by muse, mutect2, varscan2
- DOK2 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV52389583; called by muse, mutect2, varscan2
- DYSF | c.6122G>A p.R2041Q | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs760119297, COSV50504242; called by muse, mutect2, varscan2
- EHD3 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs138007410; called by muse, mutect2, varscan2
- EP400 | c.7129C>T p.R2377* | Nonsense Mutation (SNP) | VAF 41/186 reads (22%) | catalogued as COSV100200616, COSV57780685; called by muse, mutect2, varscan2
- FAM83B | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs868155358, COSV60924635; called by muse, mutect2, varscan2
- FOXK1 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762929883, COSV61067691; called by muse, mutect2, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, mutect2, varscan2
- GPR155 | c.1941T>G p.Y647* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV55040791; called by muse, mutect2, varscan2
- GRIK5 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs766656809, COSV53482804; called by muse, mutect2, varscan2
- GRN | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs148531161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HELZ2 | c.4937C>T p.A1646V (on ENST00000467148 / NM_001037335.2; = p.A1077V on NM_033405.3) | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs192795569; called by muse, mutect2, varscan2
- HRAS | c.499A>G p.K167E | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99530856; called by muse, varscan2
- HRH4 | c.527C>G p.A176G | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV56929138; called by muse, mutect2, varscan2
- KCNA1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66838104; called by muse, mutect2, varscan2
- LRP1B | c.5263G>T p.G1755* | Nonsense Mutation (SNP) | VAF 25/183 reads (14%) | catalogued as COSV101261170, COSV67200981; called by muse, mutect2, varscan2
- LYST | c.9401T>G p.L3134* | Nonsense Mutation (SNP) | VAF 58/162 reads (36%) | catalogued as COSV67711102; called by muse, mutect2, varscan2
- MAGEH1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs980329741, COSV61678955; called by muse, mutect2, varscan2
- MAPK10 | c.496A>G p.K166E (on ENST00000359221 / NM_001351625.2; = p.K204E on NM_002753.5) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60388918; called by muse, mutect2, varscan2
- MDN1 | c.12425G>A p.R4142H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753549140, COSV65526619; called by muse, mutect2, varscan2
- MIIP | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs541833150, COSV52428308; called by muse, mutect2, varscan2
- MYH7 | c.1887G>A p.A629= | Splice Region (SNP) | VAF 22/58 reads (38%) | catalogued as rs376572023, COSV62525209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5C | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.069); catalogued as rs570712265, COSV55910034; called by muse, mutect2, varscan2
- NALCN | c.3511G>A p.D1171N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51952860, COSV99213576; called by muse, mutect2
- NSD3 | c.3568C>T p.R1190* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV57672386; called by muse, mutect2, varscan2
- OR2M4 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs144805988; called by muse, mutect2, varscan2
- PCDH17 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs749151713, COSV100931554, COSV64971702; called by muse, mutect2, varscan2
- PCDHA11 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); catalogued as rs1554164932, COSV56530230; called by muse, mutect2, varscan2
- PCDHB2 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); catalogued as rs540457643, COSV50602947; called by muse, mutect2, varscan2
- PCDHGA11 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53997609; called by muse, mutect2, varscan2
- PCDHGA5 | c.2267A>T p.E756V | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV53997592; called by muse, mutect2, varscan2
- PIGK | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs751082508, COSV63063008; called by muse, mutect2, varscan2
- PLEC | c.2357C>T p.T786I (on ENST00000322810 / NM_201380.4; = p.T676I on NM_000445.5) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV59670415; called by muse, mutect2, varscan2
- PSG1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.623); catalogued as rs150536125; called by muse, mutect2, varscan2
- PYGB | c.2306A>G p.H769R | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV53821427, COSV99405127; called by muse, mutect2, varscan2
- RIPK1 | c.1685C>T p.T562M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs367576973; called by muse, mutect2, varscan2
- RNFT2 | c.956A>C p.K319T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV57488405; called by muse, mutect2, varscan2
- SALL3 | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs533436270, COSV73306302, COSV73306776; called by muse, mutect2, varscan2
- SCAI | c.710C>T p.A237V (on ENST00000336505 / NM_001144877.3; = p.A260V on NM_173690.5) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs373639867; called by muse, mutect2, varscan2
- SCG3 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV55022496; called by muse, mutect2, varscan2
- SDC3 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59580063; called by muse, mutect2, varscan2
- SDK1 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.845); catalogued as rs549922689, COSV67381404; called by muse, mutect2
- SEMA3D | c.2232C>A p.N744K | Missense Mutation (SNP) | VAF 78/325 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754421022, COSV52399630; called by muse, mutect2, varscan2
- SFMBT2 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs372825470; called by muse, mutect2, varscan2
- SGSM1 | c.3257C>T p.A1086V (on ENST00000400359 / NM_001039948.4; = p.A1025V on NM_133454.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.345); catalogued as rs376703589; called by muse, mutect2, varscan2
- SLC23A2 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV57772245; called by muse, mutect2, varscan2
- SLC25A4 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV55669510; called by muse, mutect2, varscan2
- SPATS2 | c.944_946del p.K315del | In Frame Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs1565762329; called by pindel, varscan2
- SPOCK1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs201506391, COSV56444136; called by muse, mutect2, varscan2
- SYNE1 | c.15850G>A p.A5284T (on ENST00000367255 / NM_182961.4; = p.A5213T on NM_033071.3) | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs148292669; called by muse, mutect2, varscan2
- SYTL5 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52903556; called by muse, mutect2, varscan2
- TIMD4 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs200184575, COSV50854542; called by muse, mutect2, varscan2
- TNFAIP1 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs782624780, COSV56877409; called by muse, mutect2, varscan2
- TNFAIP6 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200351871; called by muse, mutect2, varscan2
- TNRC6A | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV59368050; called by muse, mutect2, varscan2
- TRPC7 | c.2299A>T p.N767Y | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV61461034; called by muse, mutect2, varscan2
- TTN | c.24688G>T p.E8230* (on ENST00000591111; = p.E7303* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV60224920; called by muse, mutect2, varscan2
- TULP1 | c.1503T>A p.Y501* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV57693390; called by muse, mutect2, varscan2
- VPS18 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99592755; called by muse, mutect2, varscan2
- ANKRD11 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CEP250 | c.1744_1745del p.S582Ffs*2 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- FCGBP | c.10454C>T p.P3485L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- GARRE1 | c.2229_2237del p.Q744_P746del | In Frame Del (DEL) | VAF 25/61 reads (41%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 75/112 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLTM | c.258dup p.H87Tfs*2 | Frame Shift Ins (INS) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- USH2A | c.15507_15519+2del p.X5169_splice | Splice Site (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel
- ABCB8 | c.1041C>T p.F347= (on ENST00000297504 / NM_001282291.2; = p.F330= on NM_007188.5) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1140980; called by mutect2, varscan2
- ADAMTS17 | c.2517C>T p.N839= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs750422781, COSV51488415; called by muse, mutect2, varscan2
- ADGRV1 | c.7647C>T p.N2549= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV101316524; called by muse, mutect2, varscan2
- ARHGEF1 | c.2724G>A p.Q908= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV61528974; called by muse, mutect2, varscan2
- ARHGEF18 | c.3216G>A p.P1072= (on ENST00000359920 / NM_001130955.2; = p.P968= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs578103182, COSV60472363; called by muse, mutect2, varscan2
- CALHM1 | c.501C>T p.G167= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs772556161, COSV61708075; called by muse, mutect2, varscan2
- FLG2 | c.2082C>A p.G694= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as COSV101166229, COSV66173817; called by muse, mutect2, varscan2
- FREM2 | c.5097C>T p.I1699= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs537753004, COSV54845735; called by muse, mutect2, varscan2
- HOXD11 | c.795G>A p.R265= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV50910392, COSV50912453; called by muse, mutect2, varscan2
- KRT38 | c.114C>A p.A38= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV55846989; called by muse, mutect2, varscan2
- MRGPRF | c.822C>T p.Y274= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs144312357; called by muse, mutect2, varscan2
- OBSCN | c.12492G>A p.G4164= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as rs369076627; called by muse, mutect2, varscan2
- PCDHGA6 | c.1734G>A p.A578= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs376557886, COSV53953262, COSV53999620; called by muse, mutect2, varscan2
- PLXND1 | c.5658G>A p.P1886= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs755134184, COSV100140408; called by muse, mutect2, varscan2
- SLFN13 | c.948G>T p.V316= | Silent (SNP) | VAF 65/149 reads (44%) | catalogued as COSV53194785; called by muse, mutect2, varscan2
- SPATA31D1 | c.153G>A p.S51= | Silent (SNP) | VAF 68/267 reads (25%) | catalogued as rs774360466, COSV61195517; called by muse, mutect2, varscan2
- ST6GAL2 | c.459C>T p.P153= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs142520495, COSV64529387; called by muse, mutect2, varscan2
- USH2A | c.11715C>T p.R3905= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV56407454; called by muse, mutect2, varscan2
- ZBTB32 | c.498C>T p.H166= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs753319110, COSV52891809; called by muse, mutect2, varscan2
- MAP2 | c.5074-2079A>C | Intron (SNP) | VAF 14/79 reads (18%) | catalogued as COSV99561733; called by muse, mutect2, varscan2
- RPL26P30 | n.590G>A | RNA (SNP) | VAF 9/58 reads (16%) | catalogued as rs376134276; called by muse, mutect2, varscan2
- SWI5 | c.-113G>T | 5'UTR (SNP) | VAF 7/35 reads (20%) | catalogued as rs201440197, COSV60792705; called by muse, mutect2, varscan2
- TTN | c.34264+4833G>A | Intron (SNP) | VAF 24/134 reads (18%) | catalogued as rs576436744, COSV60147906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBTFL2 | n.500T>C | RNA (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
